Surgical pathology report (de-identified scan), TCGA case TCGA-CN-A640, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-A640-01A (Primary Tumor).

[page 1 of 6]
Pathology Repc

Report Type .

Date of Event

Sex F

Authored by

Hosp/Group

Record Status FINAL

ICD-O-3

*Carcinoma, squamous
cell NOS 8070/3*

Site: Tongue NOS 002.9

JW 5/10/13

FINAL DIAGNOSIS:

PART 1: TONGUE, RIGHT, HEMIGLOSSECTOMY

A. INVASIVE SQUAMOUS CELL CARCINOMA MODERATELY DIFFERENTIATED
WITH

HIGHLY INFILTRATIVE BORDER (3.5 CM), INVOLVING SKELETAL MUSCLE.

B. PERINEURAL INVASION PRESENT.

C. MARGINS FREE OF TUMOR (see also Part 2).

D. PATHOLOGIC STAGE: pT2N2b.

PART 2: FLOOR OF MOUTH, RIGHT, EXCISION
NO TUMOR PRESENT.

PART 3: LYMPH NODES, LEVEL 1A, SELECTIVE DISSECTION
FOUR LYMPH NODES, NO TUMOR PRESENT (0/4).

PART 4: LYMPH NODES, RIGHT NECK LEVEL 1B, SELECTIVE DISSECTION
A. THREE LYMPH NODES, NO TUMOR PRESENT (0/3).

B. MILD CHRONIC SIALADENITIS.

PART 5: LYMPH NODES, RIGHT NECK LEVELS 2 THROUGH 5, SELECTIVE
DISSECTION

A. METASTATIC SQUAMOUS CELL CARCINOMA IN TWO OF THIRTY LYMPH
NODES
(2/30).

B. POSITIVE LYMPH NODES IN LEVEL 2 AND 3 (LARGEST: 2.7 CM).

C. EXTENSIVE EXTRANODAL EXTENSION WITH INVOLVEMENT OF INTERNAL
JUGULAR VEIN ADVENTITIA, AND SKELETAL MUSCLE.

D. NECK DISSECTION MARGINS FREE OF TUMOR.

PART 6: LYMPH NODES, LEFT NECK LEVEL 1B, SELECTIVE DISSECTION

A. TWO LYMPH NODES, NO TUMOR PRESENT (0/2).

B. MILD CHRONIC SIALADENITIS.

PART 7: LYMPH NODE, LEFT NECK LEVEL 2 THROUGH 4, SELECTIVE DISSECTION
TWENTY-FOUR LYMPH NODES, NO TUMOR PRESENT (0/24).

Pathologist:

** Report Electronically Signed Out **

By Pathologist:

My signature is attestation that I have personally reviewed the
submitted
material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

Part 1 is received fresh for intraoperative consultation labeled with
patient'

s name, initials XX, and "right glossectomy". The specimen consists of
a

hemiglossectomy that measures 6.5 cm from anterior to posterior, 3.5 cm
from

[page 2 of 6]
midline to lateral, and 3 cm from superior to inferior. There is an ulcerated lesion on the lateral side of the tongue with the ulceration measuring 3 x 1.5 cm. The inferior mucosal margin was taken for intraoperative consultation. The specimen was inked and serially sectioned revealing a firm white tumor measuring 3.5 x 2.4 x 2.2 cm. The tumor comes to within 0.8 cm from the midline, 1.2 from the anterior tip mucosa, 2.3 from the posterior, 0.6 from the inferior mucosal margin, and 0.3 cm from the deep margin. The tumor focally abuts the deep edge (see part two which is additional tissue taken around this area). Gross photographs are taken. Representative sections are submitted as follows:

- 1AFS- frozen inferior mucosal margin resubmitted
- 1B- anterior tip margin
- 1C- posterior shave margin
- 1D- tumor and midline margin, perpendicular cut
- 1E-F- remainder of midline margin shave
- 1G- Tumor and area where it abuts deep edge
- 1H- Tumor and deep margin
- 1I-J- tumor

INK CODE:

- Blue- anterior
- Green- posterior
- Black- medial
- Red- area banked
- Yellow- inferior mucosal edge
- Orange- deep

Time in formalin: 32 hours

Part 2 is received fresh labeled with patient's name, initials XX, and "right

floor of mouth". The specimen consists of salivary gland and attached soft tissue that measure 3 x 1.0 x 0.7 cm. The specimen was oriented by the surgeon

who communicated that this was deeper tissue taken from the area of concern in

part 1. The deepest margin is inked orange according to the surgeon's orientation. Two separate pieces of tan-brown soft tissue is also present and

measure 2 x 1.5 x 0.5 cm and 1 x 1 x 0.4 cm. The specimen is serially sectioned and entirely submitted as follows:

- 2A-B- salivary gland with deepest margin inked
- 2C- separate fragments of soft tissue

Time in formalin- 32 hours

Part 3 is received fixed labeled with patient's name, initials XX, and "level

1A". It consists of adipose tissue and associated lymph nodes with an overall

measurement of 4.3 x 4 x 1.5 cm. Several lymph nodes are identified and range

in size from 0.2 x 0.2 x 0.2 cm up to 1.0 x 0.6 x 0.5 cm. The lymph nodes are

submitted in two cassettes labeled 3A and 3B.

[page 3 of 6]
Time in formalin- 11 hours.

Part 4 is received fixed labeled with patients name, initials XX, and "right neck level 1B". It consists of adipose tissue, submandibular gland and associated lymph nodes with an overall measurement of 5.7 x 4 x 2 cm. The submandibular gland measures 4.5 x 2.2 x 1.5 cm and is serially sectioned to reveal a lobulated white parenchyma. Several lymph nodes are identified and range in size from 0.5 x 0.3 x 0.3 cm up to 1.2 x 1.2 x 1.0 cm. The specimen is submitted as follows:

4A- One lymph node bisected

4B- Lymph nodes

4C-D- representative sections of the submandibular gland.

Time in formalin- 11 hours.

Part 5 is received fixed labeled with patient' s name, initials XX, and "right neck level 2, 3, 4, 5". The specimen consists of an unoriented radical neck dissection which measures 13 x 8.5 x 3.5 cm, a separate piece of muscle which measures 4.5 x 3.8 x 2.0 cm and a separate piece of fibroadipose tissue which measures 4.5 x 2.0 x 0.8 cm.

The radical neck dissection piece also contains a piece of muscle which measures 3.8 x 3.5 x 2.8 and a jugular vein (3.5 cm long and 0.7 cm in diameter). Between level 2 and 3 is a mass formed by two ill-defined nodules,

one that is proximal (2.7x 2.2 x 1.7 cm) and another that is distal (2 x 1.7 x

1.5 cm). The proximal mass is adjacent to the jugular vein and the distal

mass involves the muscle. The remaining fibroadipose tissue contains multiple

lymph nodes (0.2 to 1.7 cm in maximal dimension). The piece of muscle that was

separate grossly is not involved by tumor.

Section Code:

5A- Level 2 lymph nodes

5B- Proximal mass

5C- Proximal mass and jugular vein

5D- Jugular vein proximal resection margin

5E- Jugular vein distal resection margin

5F-5G- Distal mass and muscle

5H- Muscle proximal resection margin

5I- Muscle distal resection margin

5J-5K- Level 3 lymph nodes

5L-5O- level 4 and 5 lymph nodes (5L and 5M one lymph node in each, bisected)

5P- lymph nodes from separate fibroadipose tissue

Time in formalin-11 hours.

Part 6 is received fixed labeled with patient' s name, initials XX, and "left neck level 1B". It consists of adipose tissue, submandibular gland and

[page 4 of 6]
associated lymph nodes with an overall measurement of 5.5 x 4.5 x 2 cm. The submandibular gland measures 5.0 x 4 x 3 cm and is serially sectioned to reveal a lobulated white parenchyma. Two lymph nodes are identified and measure 1.0 x 0.7 x 0.3 cm and 1.4 x 0.7 x 0.5 cm. The specimen is submitted as follows:

6A- Lymph nodes

6B-C- representative sections of the submandibular gland.

Time in formalin- 11 hours.

Part 7 is received fixed labeled with patient' s name, initials XX, and "left

neck level 2, 3, 4, stitch marks level 2". It consists of adipose tissue and

associated lymph nodes with an overall measurement of 12.0 x 4.3 x 1.5 cm.

Several lymph nodes are identified in level 2, 3, and 4 and range in size from

0.4 x 0.2 x 0.2 cm up to 2.0 x 1.0 x 1.0 cm. The lymph nodes are submitted as

follows:

7A- One lymph node bisected, level 2

7B- level 2 lymph nodes

7C-D- level 3 lymph nodes

7E-G- level 4 lymph nodes

Time in formalin- 11 hours.

INTRAOPERATIVE CONSULTATION:

1AFS: INFERIOR MUCOSAL MARGIN, RIGHT TONGUE (frozen section):

A. SUFFICIENT FOR ANCILLARY STUDIES.

B. BENIGN.

C. NO TUMOR SEEN

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by

the department of Pathology, as required by the CLIA

'88 regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation

ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical

testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory

have been established and verified for accuracy and precision.

Additional

information about this type of test is available upon request.

CASE SYNOPSIS:

[page 5 of 6]
SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY
GLAND

TUMORS

SPECIMEN TYPE: Resection: HEMIGLOSSECTOMY
TUMOR SITE: Oral Cavity
TUMOR SIZE: Greatest dimension: 3.5 cm
HISTOLOGIC TYPE: Squamous cell carcinoma, conventional
HISTOLOGIC GRADE: G2
PRIMARY TUMOR (pT): pT2
REGIONAL LYMPH NODES (pN): pN2b
Number of regional lymph nodes examined: 63
Number of regional lymph nodes involved: 2
Extra-capsular extension of nodal tumor: Present
DISTANT METASTASIS (pM): pMX
MARGINS: Margins uninvolved by tumor
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):
Present
PERINEURAL INVASION: Present

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Tongue Cancer
PROCEDURE: Right neck dissection, hemiglossectomy
SPECIFIC CLINICAL QUESTION: Not given
OUTSIDE TISSUE DIAGNOSIS: Not given
PRIOR MALIGNANCY: Not given
CHEMORADIATION: Not given
ORGAN TRANSPLANT: Not given
IMMUNOSUPPRESSION: Not given
OTHER DISEASES: Not given
HISTO TISSUE SUMMARY/SLIDES REVIEWED:
Part 1: Right Glossectomy

Stain, Block

H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H
H&E x 1 I
H&E x 1 J

Part 2: Right Floor of Mouth

Stain, Block

H&E x 1 A
H&E x 1 B
H&E x 1 C

Part 3: Level 1A

Stain, Block

H&E x 1 A
H&E x 1 B

Part 4: Right Neck Level 1B

[page 6 of 6]
Stain Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

Part 5: Right Neck Dissection Levels 2-5

Stain Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

H&E x 1 I

H&E x 1 J

H&E x 1 K

H&E x 1 L

H&E x 1 M

H&E x 1 N

H&E x 1 O

H&E x 1 P

Part 6: Left Neck Level 1B

Stain Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

Part 7: Left neck Level 2-4

Stain Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

HI/PA Discrepancy		☒

Source: NCI Genomic Data Commons file 24eff359-1fb3-41ba-97ac-d7f08a4b0ece (TCGA-CN-A640.D5277DE4-EC4C-4DF5-9115-CDCE0085575B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).